Somatic mutation profile of tumor specimen TARGET-10-PARKZX-09A (aliquot TARGET-10-PARKZX-09A-01D) from TARGET case TARGET-10-PARKZX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.0 years (4,739 days).
Specimen TARGET-10-PARKZX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce8101a6-9412-429f-a25a-d258840f29c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARKZX-10A (Blood Derived Normal), aliquot TARGET-10-PARKZX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77045aee-061f-40ed-8626-c786c44d961f

The open-access MAF lists 40 somatic variants for this specimen: 25 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 11, Nonsense Mutation 3, RNA 2, Frame Shift Del 1, Splice Site 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS13 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782209298; called by muse, mutect2, varscan2
- CACNA2D3 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as rs1553898213, COSV55549370; called by muse, mutect2, varscan2
- CAPZA3 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs151069259; called by muse, mutect2, varscan2
- CCL14 | c.137G>A p.R46H (on ENST00000618404 / NM_032963.4; = p.R62H on NM_032962.4) | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs144903710; called by muse, mutect2, varscan2
- DCAF8L2 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs777466794, COSV70551102; called by muse, varscan2
- DYNC1I1 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.581); catalogued as rs187401312; called by muse, mutect2, varscan2
- FLT3 | c.1727T>C p.L576P | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV54047457, COSV54049031, COSV54049919; called by muse, mutect2, varscan2
- GRIP2 | c.1523G>A p.R508H (on ENST00000619221; = p.R411H on NM_001080423.4) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs751081618; called by muse, varscan2
- NFIA | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs771496016, COSV100963557; called by muse, mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 19/102 reads (19%) | catalogued as rs746200712; called by mutect2, varscan2
- PAX1 | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.57); PolyPhen possibly damaging (0.694); catalogued as rs1291243694; called by muse, varscan2
- PCM1 | c.4195C>T p.R1399C | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs967829705; called by muse, mutect2, varscan2
- PDZD2 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752571546, COSV56860471; called by muse, mutect2, varscan2
- PHKA1 | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782514332, COSV59803879; called by muse, mutect2, varscan2
- RFX4 | c.707C>T p.P236L (on ENST00000392842 / NM_213594.3; = p.P142L on NM_032491.6) | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs778269709, COSV57578462; called by muse, varscan2
- SETD2 | c.3343G>T p.E1115* | Nonsense Mutation (SNP) | VAF 11/22 reads (50%) | catalogued as COSV57456631; called by muse, mutect2, varscan2
- TRIM64 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs766683408; called by muse, mutect2, varscan2
- WWC1 | c.2821C>T p.R941W | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54645152; called by muse, mutect2, varscan2
- LRRIQ1 | c.132+2T>C p.X44_splice | Splice Site (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- MED1 | c.3976G>T p.D1326Y | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.172); called by muse, mutect2
- OR4D10 | c.600T>G p.I200M | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDH9 | c.1290G>T p.E430D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PGS1 | c.1549C>A p.Q517K | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- RANGAP1 | c.71G>T p.S24I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- TPR | c.2332G>T p.E778* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- GARRE1 | c.1851C>A p.G617= | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- ICOS | c.276C>T p.V92= | Silent (SNP) | VAF 40/126 reads (32%) | called by muse, mutect2, varscan2
- JPH4 | c.255C>T p.G85= | Silent (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2
- OCRL | c.2487G>A p.P829= | Silent (SNP) | VAF 80/299 reads (27%) | catalogued as rs763309500, COSV63981587; called by muse, mutect2, varscan2
- PAPPA | c.4557C>T p.N1519= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as rs374215967; called by muse, mutect2, varscan2
- PDE7A | c.1131T>C p.S377= (on ENST00000401827 / NM_001242318.3; = p.S351= on NM_002603.4) | Silent (SNP) | VAF 52/169 reads (31%) | called by muse, mutect2, varscan2
- SDS | c.897G>T p.V299= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- SLK | c.2619A>G p.Q873= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs767047729; called by muse, mutect2, varscan2
- SPATA18 | c.48G>A p.T16= | Silent (SNP) | VAF 69/222 reads (31%) | catalogued as rs749790080; called by muse, mutect2, varscan2
- TEX2 | c.1065G>T p.G355= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV99367131; called by muse, mutect2
- VCAN | c.783C>T p.F261= | Silent (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- FAM3B | n.58G>A | RNA (SNP) | VAF 27/84 reads (32%) | catalogued as rs754664471; called by muse, mutect2, varscan2
- OCA2 | c.*42C>T | 3'UTR (SNP) | VAF 57/126 reads (45%) | called by muse, mutect2, varscan2
- POM121L4P | n.320G>A | RNA (SNP) | VAF 13/40 reads (33%) | catalogued as rs1274613117; called by muse, mutect2, varscan2
- XK | c.-14G>A | 5'UTR (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
